FM case AD414 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Primary site: Other and unspecified parts of biliary tract.
https://portal.gdc.cancer.gov/cases/1389c280-5998-4f7c-b975-7f7ca62f74b9

Male, 60.0 years: diagnosis not reported by GDC of the biliary tract. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
